Surgical pathology report (de-identified scan), TCGA case TCGA-MW-A4EC, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Miami, specimen TCGA-MW-A4EC-01A (Primary Tumor).

[page 1 of 3]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]

PAGE 1

AGE/SEX: /F
REG [REDACTED]

Path [REDACTED]

Submit Dr: [REDACTED]

SPECIMEN ID:

KIDNEY - RIGHT RENAL TUMOR MARGIN FS

100-0-3

carcinoma, renal cell, NOS 8312/3

Site: Kidney, NOS 664.9

A. RIGHT KIDNEY, RENAL TUMOR MARGIN:

Renal parenchyma, negative for carcinoma.

B. RIGHT KIDNEY, RENAL TUMOR, PARTIAL NEPHRECTOMY:

RENAL CELL CARCINOMA, conventional type (clear cell morphology), measuring 2.5 cm in greatest dimension.

Fuhrman nuclear grade II of IV.

Tumor focally involves the inked capsular resection margin (0.5 cm in linear measurement, multiple levels examined).

Parenchymal resection margin is negative for tumor.

See Surgical Pathology Cancer Case Summary.

Surgical Pathology Cancer Case Summary

Procedure: Partial nephrectomy

Specimen Laterality: Right

Tumor Size:

Greatest dimension: 2.5 cm

Additional dimensions: 2.4 x 1.8 cm

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 2 of 3]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]

PAGE 2

*** FINAL REPORT ***
SURGICAL PATHOLOGY REPORT

SPEC #: [REDACTED]

(Continued)

*** FINAL DIAGNOSIS *** (Continued)

Tumor Focality: Unifocal
Histologic Type: Clear cell renal cell carcinoma
Sarcomatoid Features: Not identified
Histologic Grade (Fuhrman Nuclear Grade):
G2: Nuclei slightly irregular, approximately 15 microns; nucleoli evident
Microscopic Tumor Extension: Tumor extension into renal capsule
Margins:
Margins involved by invasive carcinoma
Renal capsular margin (partial nephrectomy only)
Lymph-Vascular Invasion: Not identified
Pathologic Staging (pTNM):
Primary Tumor (pT):
pT1a: Tumor 4 cm or less in greatest dimension, limited to kidney
Regional Lymph Nodes (pN):
pNX: Regional lymph nodes cannot be assessed
Distant Metastasis (pM):
Not applicable

AJCC Classification (7th edition): At least pT1a, pNX, pMn/a. See note.

Comment:

Tumor focally involves the inked capsular resection margin; because perinephric adipose tissue is not present in this area, the AJCC Classification is best considered to be at least pT1a.

[REDACTED] has reviewed select slides and concurs with the diagnosis.
[REDACTED]

CLINICAL HISTORY-

PRE-OP DX: Not provided
PROCEDURE: Open partial nephrectomy
RELEVANT CLINICAL HX: Not provided

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 3 of 3]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]

PAGE 3

*** FINAL REPORT ***
SURGICAL PATHOLOGY REPORT

SPEC #: [REDACTED]

(Continued)

GROSS DESCRIPTION:

- A. Received fresh and labeled "Right renal tumor margin" is a tan soft tissue with fat attached and two small additional fragments of fat, 1.0 x 0.5 x 0.2 cm in aggregate. Submitted in toto in one cassette.
- B. Received in formalin and labeled "Right renal tumor" is a partial nephrectomy specimen with fat attached. The renal resection margin is inked black. The tumor capsule and perirenal fat are inked yellow. The specimen measures 3.2 x 3.0 x 2.9 cm. There is attached perirenal fat, 3.2 x 1.5 cm. Upon sectioning, there is a golden-yellow, pigmented tumor, 2.5 x 2.4 x 1.8 cm. There are a few areas of hemorrhage grossly identified. There is also one cyst identified, 1.0 cm in greatest dimension. Grossly, the tumor appears to have a capsule that goes through the renal capsule. The tumor does not appear to invade the perirenal fat. The tumor appears to be 1.0 cm from the renal margin. Upon further sectioning, multiple small cysts are noted; some of which are filled with clear, mucus-type material. The largest cyst is 1.0 cm in greatest dimension. Representative sections are submitted in eight cassettes.
- [REDACTED]

OPERATING ROOM CONSULT

AFS. RIGHT RENAL TUMOR MARGIN: Negative.

ATTENDING PATHOLOGIST: [REDACTED]

[REDACTED]

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

9/19/12

Source: NCI Genomic Data Commons file 67dd11d6-c950-4321-9acb-bb06055b21a4 (TCGA-MW-A4EC.3B7BABCE-8EE2-4BE7-B2F9-FFF03156E0E1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).